TARGET case TARGET-40-NAAVMK — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/5ceb0e26-ac21-5a8c-9bce-2f6395bf347b

Demographics
Sex at birth: female; Race: white; Age at index: 33 years.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 34.0 years (12,410 days).

Biospecimens (1 sample)
- Sample TARGET-40-NAAVMK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAVMK-01A-01  TS1:
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 90
- % Non Tumor Nuclei: Top from Biopsy: 10
- % Cellular Tumor: Top from Biopsy: 89
- % Normal: Top from Biopsy: 8
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 3
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
